CCDI case PBCDVT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/59804cf8-df6f-485d-9ea2-7ce3a5a73a10

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Overlapping lesion of connective, subcutaneous and other soft tissues; Age at diagnosis: 7.2 years (2,628 days).

Biospecimens (3 samples)
- Sample 0DS4L4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS4M8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS4MG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
